Somatic mutation profile of tumor specimen 695b0b00-a86b-43c0-a6c8-50a840 (aliquot 695b0b00-a86b-43c0-a6c8-50a840_D6) from CPTAC case 05CO032, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 695b0b00-a86b-43c0-a6c8-50a840: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e7726a5-f132-4a3b-a239-d007fa271963.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ccdcd5e5-685c-4cc7-b357-35a272 (Blood Derived Normal), aliquot ccdcd5e5-685c-4cc7-b357-35a272_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a98d5d31-10bc-4bab-84ab-9fe490e86547

The open-access MAF lists 1,258 somatic variants for this specimen: 836 protein-altering or splice-affecting, 243 silent, 179 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 578, Silent 243, Frame Shift Del 156, Intron 87, Frame Shift Ins 44, 3'UTR 31, Nonsense Mutation 27, 5'UTR 19, RNA 19, 5'Flank 17, Splice Region 16, Splice Site 11.

Variants (750 of 1,258; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1759del p.S587Afs*3 | Frame Shift Del (DEL) | VAF 98/515 reads (19%) | catalogued as rs1554083100, CM920037, COSV57379749; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 67/340 reads (20%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BCL10 | c.499del p.S167Lfs*6 | Frame Shift Del (DEL) | VAF 29/166 reads (17%) | catalogued as rs387906350, COSV65354275; ClinVar: pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/344 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL4A4 | c.2528G>A p.G843E | Missense Mutation (SNP) | VAF 126/552 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1559515185, COSV61634861; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 56/257 reads (22%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- KRT14 | c.356T>C p.M119T | Missense Mutation (SNP) | VAF 131/541 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28928893, CM981138; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 61/238 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TBX6 | c.704del p.G235Afs*15 | Frame Shift Del (DEL) | VAF 77/315 reads (24%) | catalogued as rs758051786, COSV54222619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TGFBR2 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 158/579 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893809, CM042122, CM064325, COSV55442890; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZNF469 | c.6360del p.Q2121Sfs*51 (on ENST00000437464; = p.Q2149Sfs*51 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 78/312 reads (25%) | catalogued as rs886044697; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA5 | c.3131C>T p.A1044V | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1282042261; called by muse, mutect2, varscan2
- ABHD4 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs142817719; called by muse, varscan2
- AC068580.4 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV52587161; called by muse, mutect2, varscan2
- ACADSB | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 75/370 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs143736049, COSV62550488; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | catalogued as rs757016425; called by mutect2, varscan2
- ACTL9 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV61007073; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 58/122 reads (48%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACYP1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 80/318 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs376319318, COSV53134559; called by muse, mutect2, varscan2
- ADAM12 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs770769845, COSV64106410; called by muse, varscan2
- ADAM28 | c.224del p.N75Tfs*53 | Frame Shift Del (DEL) | VAF 17/148 reads (11%) | catalogued as rs570442888; called by mutect2, varscan2
- ADAMTS2 | c.2371A>G p.M791V | Missense Mutation (SNP) | VAF 189/785 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.528); catalogued as rs548748579; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2471C>T p.A824V | Missense Mutation (SNP) | VAF 93/625 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.269); catalogued as rs377554910; called by muse, mutect2, varscan2
- ADCY2 | c.1578G>A p.T526= | Splice Region (SNP) | VAF 20/65 reads (31%) | catalogued as COSV57901389; called by muse, mutect2, varscan2
- ADGRL1 | c.754G>A p.A252T (on ENST00000340736 / NM_001008701.3; = p.A247T on NM_014921.5) | Missense Mutation (SNP) | VAF 142/591 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1226166895; called by muse, mutect2, varscan2
- AGGF1 | c.2042dup p.N681Kfs*11 | Frame Shift Ins (INS) | VAF 40/212 reads (19%) | catalogued as rs761190994; called by mutect2, varscan2
- AKAP3 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 76/307 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1260746821, COSV57421584; called by muse, mutect2, varscan2
- AL035461.3 | c.2819C>T p.A940V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.353); catalogued as rs769080366; called by muse, mutect2, varscan2
- ALKBH4 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs1329972545; called by muse, mutect2, varscan2
- ALOX15 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs143864254; called by muse, mutect2, varscan2
- AMD1 | c.877C>G p.R293G | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV64387445; called by muse, mutect2, varscan2
- AMELY | c.102+2T>C p.X34_splice | Splice Site (SNP) | VAF 43/136 reads (32%) | catalogued as rs758085605; called by muse, mutect2, varscan2
- ANKRD12 | c.2689del p.T897Lfs*26 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as rs1567974406, COSV100042141; called by mutect2, pindel, varscan2
- ANKRD18B | c.1176del p.V393Wfs*11 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs745540260; called by mutect2, pindel, varscan2
- ANXA7 | c.832C>T p.R278C (on ENST00000372919 / NM_001320880.2; = p.R256C on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs775887772, COSV65824302; called by muse, mutect2, varscan2
- APOB | c.12890G>A p.R4297H | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs375701380, CM138876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBEC3B | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs113792154; called by muse, mutect2, varscan2
- APOBR | c.1679dup p.A561Rfs*6 (on ENST00000431282; = p.A570Rfs*6 on NM_018690.4) | Frame Shift Ins (INS) | VAF 30/113 reads (27%) | catalogued as rs764945142; called by mutect2, pindel, varscan2
- AQR | c.3925C>G p.L1309V | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as rs1566978109; called by muse, mutect2, varscan2
- ARFIP1 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs954354610; called by muse, mutect2, varscan2
- ARHGAP4 | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782809170; called by muse, mutect2, varscan2
- ARHGAP45 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1367066416; called by muse, mutect2, varscan2
- ARHGEF12 | c.4396G>A p.A1466T | Missense Mutation (SNP) | VAF 164/708 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as COSV63105024, COSV63108073; called by muse, mutect2, varscan2
- ARHGEF16 | c.1814+1G>A p.X605_splice | Splice Site (SNP) | VAF 37/154 reads (24%) | catalogued as rs374272150; called by muse, mutect2, varscan2
- ARVCF | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs779678470; called by muse, mutect2, varscan2
- ASAP1 | c.1149dup p.S384Ifs*3 | Frame Shift Ins (INS) | VAF 42/201 reads (21%) | catalogued as rs1486733426; called by mutect2, pindel, varscan2
- ASTL | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.737); catalogued as rs373382016; called by muse, mutect2, varscan2
- ATP2A3 | c.1526G>A p.G509D | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as rs1346075661, COSV59234751; called by muse, mutect2, varscan2
- ATRNL1 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs1554873921, COSV100745378, COSV104421825; called by muse, mutect2, varscan2
- AUTS2 | c.1353dup p.A452Rfs*58 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | catalogued as rs1554481319; called by mutect2, pindel
- BARX1 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751625001, COSV54159571; called by muse, mutect2, varscan2
- BCOR | c.2607T>A p.Y869* | Nonsense Mutation (SNP) | VAF 61/211 reads (29%) | catalogued as COSV60708517, COSV60712533; called by muse, mutect2, varscan2
- BIRC6 | c.12544C>A p.Q4182K | Missense Mutation (SNP) | VAF 69/324 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV70198707; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 51/217 reads (24%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BRIP1 | c.3104G>A p.R1035H | Missense Mutation (SNP) | VAF 97/401 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.192); catalogued as rs367816363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD1 | c.353G>A p.C118Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as rs756938505; called by mutect2, varscan2
- C11orf68 | c.734C>A p.A245D (on ENST00000530188; = p.A286D on NM_031450.4) | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); catalogued as rs767900253; called by muse, mutect2
- C20orf202 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as rs899191175; called by muse, mutect2, varscan2
- C20orf204 | c.287G>T p.S96I | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV53875215; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 52/226 reads (23%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, varscan2
- CABS1 | c.401A>G p.D134G | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284970538; called by muse, mutect2, varscan2
- CACNA1E | c.5960C>T p.S1987L | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs749959606; called by muse, mutect2, varscan2
- CAMTA2 | c.2372G>A p.R791H | Missense Mutation (SNP) | VAF 105/511 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs767482239, COSV61835276; called by muse, mutect2, varscan2
- CANX | c.1305del p.F435Lfs*12 | Frame Shift Del (DEL) | VAF 38/162 reads (23%) | catalogued as rs760711956; called by mutect2, varscan2
- CBLL1 | c.419del p.K140Rfs*52 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | catalogued as rs1256378164; called by mutect2, pindel, varscan2
- CCDC105 | c.1414G>A p.V472M | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.498); catalogued as rs781133010; called by muse, mutect2, varscan2
- CCDC166 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.356); catalogued as rs1554617037; called by muse, mutect2, varscan2
- CCDC175 | c.642dup p.C215Mfs*28 | Frame Shift Ins (INS) | VAF 60/284 reads (21%) | catalogued as rs760464505; called by mutect2, varscan2
- CCDC185 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs754754030, COSV64820292, COSV99081317; called by muse, mutect2, varscan2
- CCDC27 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs185617592, COSV53899594; called by muse, mutect2, varscan2
- CCDC80 | c.1599del p.A534Qfs*21 | Frame Shift Del (DEL) | VAF 96/464 reads (21%) | catalogued as rs1414623331; called by mutect2, pindel, varscan2
- CCDC88A | c.2032dup p.T678Nfs*4 | Frame Shift Ins (INS) | VAF 22/80 reads (28%) | catalogued as rs750732366; called by mutect2, varscan2
- CD22 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs745645352, COSV50050278; called by muse, mutect2, varscan2
- CD6 | c.1247T>C p.L416P | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs754171556; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 48/159 reads (30%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH9 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 98/443 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1402112195, COSV50251062, COSV50289480; called by muse, mutect2, varscan2
- CDHR2 | c.773C>A p.T258N | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs774560711; called by muse, mutect2, varscan2
- CELSR3 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs138744037; called by muse, mutect2, varscan2
- CEP170B | c.4271G>A p.R1424Q (on ENST00000453495; = p.R1353Q on NM_015005.3) | Missense Mutation (SNP) | VAF 66/265 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.3); catalogued as rs571111410, COSV99229822; called by muse, mutect2, varscan2
- CEP290 | c.4328C>T p.P1443L | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100470191; called by muse, mutect2
- CHD5 | c.3359C>T p.S1120L | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99314307; called by muse, mutect2, varscan2
- CHRNB3 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs759488366, COSV51494137, COSV51497556; called by muse, mutect2, varscan2
- CLEC4A | c.236dup p.T80Dfs*35 | Frame Shift Ins (INS) | VAF 12/84 reads (14%) | catalogued as rs1182229842; called by mutect2, varscan2
- CLU | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 161/651 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs756208273, COSV100324259, COSV100324464; called by muse, mutect2, varscan2
- CNDP1 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 56/263 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758603848, COSV62595329; called by muse, mutect2, varscan2
- COBL | c.121dup p.H41Pfs*31 | Frame Shift Ins (INS) | VAF 46/242 reads (19%) | catalogued as rs778516787; called by mutect2, varscan2
- COG5 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs142839642; called by muse, varscan2
- COL5A3 | c.3143del p.P1048Lfs*96 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs771976753; called by mutect2, pindel, varscan2
- COL9A3 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201219004, COSV100102680, COSV58983511; called by muse, mutect2, varscan2
- COMP | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV55875543; called by muse, mutect2, varscan2
- CPSF3 | c.1972G>A p.G658R | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs891906066; called by muse, mutect2, varscan2
- CPT1A | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 88/443 reads (20%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.77); catalogued as rs1458280100; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs769538822; called by mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 28/126 reads (22%) | catalogued as rs747248693; called by mutect2, varscan2
- CSF2RA | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 70/488 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754889776, COSV62624178; called by muse, mutect2, varscan2
- CSKMT | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 93/461 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV63472824; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 47/251 reads (19%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 40/216 reads (19%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- CTAG2 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 164/333 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV55997368; called by muse, mutect2, varscan2
- CTAGE9 | c.176dup p.L59Ffs*6 | Frame Shift Ins (INS) | VAF 132/612 reads (22%) | catalogued as rs752217831; called by mutect2, varscan2
- CUBN | c.3914A>G p.H1305R | Missense Mutation (SNP) | VAF 26/679 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1200636588; called by muse, mutect2
- CUL4A | c.1129G>A p.E377K (on ENST00000375440 / NM_001008895.4; = p.E277K on NM_003589.3) | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs368810881; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as rs772257590; called by mutect2, varscan2
- CYC1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 79/330 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.589); catalogued as rs780653499; called by muse, mutect2, varscan2
- CYP4F2 | c.986-3del | Splice Region (DEL) | VAF 20/81 reads (25%) | catalogued as rs1271723179; called by mutect2, pindel, varscan2
- CYSLTR1 | c.671dup p.N224Kfs*6 | Frame Shift Ins (INS) | VAF 60/132 reads (45%) | catalogued as rs766746913; called by mutect2, varscan2
- DAGLA | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs757531092, COSV57198622; called by muse, mutect2, varscan2
- DAPK2 | c.1033-7del | Splice Region (DEL) | VAF 17/84 reads (20%) | catalogued as rs753638020; called by mutect2, varscan2
- DBF4B | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs368242633; called by muse, mutect2, varscan2
- DCHS2 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 69/308 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59735426; called by muse, mutect2, varscan2
- DDX39B | c.736-3del | Splice Region (DEL) | VAF 7/28 reads (25%) | catalogued as rs755280697; called by mutect2, pindel, varscan2
- DDX60L | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV99488168; called by muse, mutect2, varscan2
- DHCR7 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 149/655 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as rs1555146436, CM001126, COSV100831833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP3 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1435947284; called by muse, mutect2
- DMRTA1 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1049308354; called by muse, mutect2, varscan2
- DNAH1 | c.8371G>A p.E2791K | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs375976311; called by muse, mutect2, varscan2
- DNAH1 | c.10792C>T p.R3598W | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1281836678, COSV70227838; called by muse, mutect2, varscan2
- DNAH17 | c.9712G>A p.A3238T | Missense Mutation (SNP) | VAF 105/480 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs544265272; called by muse, mutect2, varscan2
- DNMT1 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 140/594 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761410935; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 34/124 reads (27%) | catalogued as rs782552436; called by mutect2, varscan2
- DPY19L3 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1464307499, COSV100639270, COSV60476419; called by muse, mutect2, varscan2
- DPYSL4 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); catalogued as rs1339930692; called by muse, mutect2, varscan2
- DSG3 | c.1906del p.L636Ffs*4 | Frame Shift Del (DEL) | VAF 24/117 reads (21%) | catalogued as rs754828449; called by mutect2, pindel, varscan2
- DYTN | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65971009; called by muse, mutect2, varscan2
- EBF1 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs773008354, COSV58175653; called by muse, varscan2
- EEF1D | c.422del p.P141Qfs*144 | Frame Shift Del (DEL) | VAF 70/295 reads (24%) | catalogued as COSV52784352; called by mutect2, varscan2
- EMILIN3 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 115/435 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1303438363; called by muse, mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | catalogued as rs770453803; called by mutect2, varscan2
- EMP1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs767672209; called by muse, mutect2, varscan2
- ENG | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 88/350 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.475); catalogued as rs775442178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ETV7 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as rs112097296, COSV60317142; called by muse, mutect2, varscan2
- EXOC2 | c.25dup p.L9Pfs*9 | Frame Shift Ins (INS) | VAF 25/150 reads (17%) | catalogued as rs748159069; called by mutect2, varscan2
- EXT1 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 91/397 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV65482318; called by muse, mutect2, varscan2
- FAM189A1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs750093165; called by muse, mutect2, varscan2
- FAM214A | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.38); catalogued as rs752429902; called by muse, mutect2, varscan2
- FASN | c.4618del p.D1540Tfs*60 | Frame Shift Del (DEL) | VAF 102/431 reads (24%) | catalogued as rs1304684864, COSV60761053; called by mutect2, varscan2
- FASTK | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 69/341 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs761176338; called by muse, mutect2, varscan2
- FBXL17 | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 36/185 reads (19%) | catalogued as COSV62849595; called by muse, mutect2, varscan2
- FBXL18 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs1435100280, COSV101154665; called by muse, mutect2, varscan2
- FBXO46 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.706); catalogued as rs755087299; called by muse, mutect2, varscan2
- FCGBP | c.11672G>A p.R3891H | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs780105651; called by muse, mutect2, varscan2
- FLG | c.7597C>T p.R2533C | Missense Mutation (SNP) | VAF 175/867 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.523); catalogued as rs373225696; called by muse, mutect2, varscan2
- FLRT1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 97/385 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs1470446405; called by muse, mutect2, varscan2
- FLT4 | c.2881C>T p.R961C | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs868478447; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | catalogued as rs752538869; called by mutect2, pindel
- FRMD4A | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as rs1564626656, COSV99198408; called by muse, mutect2, varscan2
- FRYL | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 85/349 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766156713, COSV99975513; called by muse, mutect2, varscan2
- FUS | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 57/240 reads (24%) | catalogued as COSV99568290, COSV99568347; called by muse, mutect2, varscan2
- FUT7 | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441462107, COSV55797520; called by muse, mutect2, varscan2
- FZD10 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 107/427 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.107); catalogued as COSV57474645; called by muse, mutect2, varscan2
- FZD7 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV99636713; called by muse, mutect2, varscan2
- FZD9 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 15/322 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs921087014; called by muse, mutect2
- GCN1 | c.5749dup p.R1917Pfs*5 | Frame Shift Ins (INS) | VAF 92/453 reads (20%) | catalogued as rs1566300826; called by mutect2, pindel, varscan2
- GDA | c.1073T>C p.V358A | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.04); catalogued as rs762642151; called by muse, mutect2, varscan2
- GGPS1 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 70/267 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1413398840, COSV51396879; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 58/259 reads (22%) | catalogued as rs763147690; called by mutect2, varscan2
- GLDN | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.642); catalogued as rs765286496; called by mutect2, varscan2
- GLI3 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 115/503 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.235); catalogued as rs1408670754, COSV67885547; called by muse, mutect2, varscan2
- GLIPR1L2 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.758); catalogued as rs763638046; called by muse, mutect2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 31/105 reads (30%) | catalogued as rs749150409; called by mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 34/182 reads (19%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPR6 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 14/325 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51572663; called by muse, mutect2
- GPSM3 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs751020910; called by muse, mutect2
- GPX4 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs779416718; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 38/135 reads (28%) | catalogued as rs760757380; called by mutect2, varscan2
- GRTP1 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs896910644; called by muse, mutect2, varscan2
- GSG1L2 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 72/307 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs978143766; called by muse, mutect2, varscan2
- GUF1 | c.1927A>G p.K643E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs545503516, COSV54945907; called by muse, mutect2, varscan2
- GUK1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs776681463, COSV57157219; called by muse, mutect2, varscan2
- GZMM | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs556049813; called by muse, mutect2, varscan2
- H3C7 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); catalogued as rs761937041; called by muse, mutect2, varscan2
- HAP1 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57881169; called by muse, mutect2, varscan2
- HAUS5 | c.781C>A p.L261M | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99178870; called by muse, mutect2, varscan2
- HAUS8 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs776600450; called by muse, mutect2, varscan2
- HEATR5B | c.3412C>T p.R1138W | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs148287014; called by muse, mutect2, varscan2
- HERC1 | c.13372C>T p.R4458C | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs770067924, COSV101496289; called by muse, mutect2, varscan2
- HK2 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 90/422 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.306); catalogued as rs375609405, COSV51878116; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 75/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs770625804; called by muse, mutect2, varscan2
- HPS3 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 115/504 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs765524486; called by muse, mutect2, varscan2
- HRC | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs750655475, COSV99043282; called by muse, mutect2, varscan2
- HTRA2 | c.346dup p.A116Gfs*22 | Frame Shift Ins (INS) | VAF 22/112 reads (20%) | catalogued as rs779457274; called by mutect2, varscan2
- IBTK | c.3176C>T p.A1059V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs191661846, COSV60392968; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 26/125 reads (21%) | catalogued as rs747841314; called by mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 59/172 reads (34%) | catalogued as rs760021495; called by mutect2, varscan2
- IGFBP5 | c.120del p.S41Afs*17 | Frame Shift Del (DEL) | VAF 16/93 reads (17%) | catalogued as rs748087175; called by mutect2, varscan2
- IGHE | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 109/452 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs782508861; called by muse, mutect2, varscan2
- IGHM | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 145/689 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.691); catalogued as rs781852051; called by muse, mutect2, varscan2
- IGLJ3 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.205); catalogued as rs367821564; called by muse, varscan2
- INTS12 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100415597; called by muse, mutect2, varscan2
- IQGAP1 | c.2822del p.N941Ifs*8 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs771739474; called by mutect2, varscan2
- IQGAP3 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370931618; called by muse, mutect2, varscan2
- IQSEC1 | c.2572C>T p.R858W | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1232118149, COSV56226447; called by muse, mutect2
- IRGC | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 70/283 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs558557281, COSV54983636; called by muse, mutect2, varscan2
- ITPKB | c.2365C>T p.R789W | Missense Mutation (SNP) | VAF 75/368 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1442556939; called by muse, mutect2, varscan2
- KCNG1 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs577545086, COSV100856988; called by muse, mutect2, varscan2
- KCNH5 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 82/453 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs150842380; called by muse, mutect2, varscan2
- KCTD8 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 67/419 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99077652; called by muse, mutect2, varscan2
- KDM2B | c.77del p.K26Rfs*81 | Frame Shift Del (DEL) | VAF 13/104 reads (13%) | catalogued as rs782541016; called by mutect2, pindel, varscan2
- KDM6A | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 157/335 reads (47%) | catalogued as CM092440, COSV65038641; called by muse, mutect2, varscan2
- KIAA1755 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.116); catalogued as rs1191917694; called by muse, mutect2, varscan2
- KIAA2012 | c.2536del p.T846Qfs*16 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs753894409; called by mutect2, varscan2
- KLB | c.2605dup p.V869Gfs*32 | Frame Shift Ins (INS) | VAF 41/240 reads (17%) | catalogued as rs34101901; called by mutect2, pindel, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | catalogued as rs749011008; called by mutect2, pindel, varscan2
- KLHL6 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 45/293 reads (15%) | catalogued as rs781649953; called by muse, mutect2, varscan2
- KSR2 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs186683317; called by muse, varscan2
- L3MBTL4 | c.1298C>G p.S433C | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as rs759479445; called by muse, mutect2, varscan2
- LCN8 | c.119G>A p.G40D (on ENST00000612714 / NM_001345934.1; = p.G17D on NM_178469.3) | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs200546113; called by muse, mutect2, varscan2
- LILRA6 | c.956-1G>T p.X319_splice | Splice Site (SNP) | VAF 37/272 reads (14%) | catalogued as COSV54434067; called by mutect2, varscan2
- LLGL2 | c.2579G>T p.G860V | Missense Mutation (SNP) | VAF 90/313 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs756629369; called by muse, mutect2, varscan2
- LRP3 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 69/276 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs141872606; called by muse, mutect2, varscan2
- LRRC3B | c.766A>G p.S256G | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV67520373; called by muse, mutect2
- LRRC41 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs947096262; called by muse, mutect2, varscan2
- LRRCC1 | c.3001C>T p.R1001C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769047718, COSV64483169; called by muse, mutect2, varscan2
- LYST | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as rs1408975983, COSV67707044; called by muse, mutect2, varscan2
- LZTS3 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.232); catalogued as rs746884158; called by muse, mutect2
- MAGEC1 | c.2201A>G p.E734G | Missense Mutation (SNP) | VAF 103/260 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV53582789; called by muse, mutect2, varscan2
- MAP3K21 | c.2824G>A p.V942M | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs750380229, COSV64041506; called by muse, mutect2, varscan2
- MARVELD3 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 65/347 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs563352434; called by muse, mutect2, varscan2
- MAU2 | c.650A>G p.N217S | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.014); catalogued as rs1380631219; called by muse, mutect2, varscan2
- MDM2 | c.961del p.L321Ffs*52 | Frame Shift Del (DEL) | VAF 33/161 reads (20%) | catalogued as rs746910913; called by mutect2, pindel, varscan2
- ME1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200396179; called by muse, mutect2, varscan2
- MGAM | c.4529G>A p.R1510H | Missense Mutation (SNP) | VAF 71/325 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760340491, COSV72075067; called by muse, mutect2, varscan2
- MKRN2 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs768823128, COSV50106817; called by muse, mutect2, varscan2
- MMGT1 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV60003899; called by muse, mutect2, varscan2
- MMS19 | c.2530C>T p.L844F | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs759888761; called by muse, mutect2, varscan2
- MN1 | c.3457del p.L1153Wfs*25 | Frame Shift Del (DEL) | VAF 52/322 reads (16%) | catalogued as rs1359870052; called by mutect2, pindel, varscan2
- MOB2 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.209); catalogued as rs1198772605; called by muse, mutect2, varscan2
- MOB3C | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 93/367 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs538105910; called by muse, mutect2, varscan2
- MRPL35 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs145456242; called by muse, mutect2, varscan2
- MXRA5 | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54224115; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 38/148 reads (26%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYH13 | c.4327T>C p.C1443R | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs749320412; called by muse, varscan2
- MYH2 | c.3542G>A p.R1181H | Missense Mutation (SNP) | VAF 156/654 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs773196254, COSV55446689; called by muse, mutect2, varscan2
- MYOM2 | c.3762G>T p.K1254N | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.915); catalogued as rs376914967; called by mutect2, varscan2
- MYT1L | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV67733244; called by muse, mutect2, varscan2
- NAALADL1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 72/314 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs772880783, COSV100368085, COSV60523612; called by muse, mutect2, varscan2
- NANOG | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.661); catalogued as rs751276167, COSV57550843; called by muse, mutect2, varscan2
- NDEL1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758224945, COSV55329854; called by muse, mutect2, varscan2
- NDUFS1 | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.248); catalogued as rs746500004, COSV51913393; called by mutect2, varscan2
- NEFL | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55336932; called by muse, mutect2
- NEURL4 | c.3547C>T p.R1183* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as rs370632013; called by muse, mutect2, varscan2
- NIT1 | c.2+6A>G | Splice Region (SNP) | VAF 42/209 reads (20%) | catalogued as rs1452097207; called by muse, mutect2, varscan2
- NLRP6 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as rs142922223; called by muse, mutect2, varscan2
- NOL8 | c.418-8del | Splice Region (DEL) | VAF 16/35 reads (46%) | catalogued as rs756440973; called by mutect2, varscan2
- NOP53 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs771411047; called by muse, mutect2, varscan2
- NPTX2 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1303685703, COSV99674651; called by muse, mutect2
- NRXN1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs756908062, COSV68039489; called by muse, mutect2, varscan2
- NSA2 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV99713613; called by muse, mutect2, varscan2
- NTM | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 92/360 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.75); catalogued as rs758413842, COSV66198956; called by muse, mutect2, varscan2
- NTM | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as rs1349351710, COSV100869155; called by muse, mutect2, varscan2
- NUAK1 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 188/740 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as rs1022920336; called by muse, mutect2, varscan2
- NUP155 | c.2325G>T p.K775N (on ENST00000231498 / NM_153485.3; = p.K716N on NM_004298.4) | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as COSV51528553; called by muse, mutect2, varscan2
- NUP98 | c.5329C>T p.R1777* (on ENST00000359171 / NM_001365126.1; = p.R1760* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 86/396 reads (22%) | catalogued as COSV51709950; called by muse, mutect2, varscan2
- NXPE2 | c.1226A>G p.Q409R | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as rs908210492; called by muse, mutect2, varscan2
- OAZ1 | c.640A>G p.M214V | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1459736359; called by muse, mutect2, varscan2
- OR11L1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 135/637 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as rs768876019, COSV100869464, COSV63314922; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 143/618 reads (23%) | catalogued as rs755413956; called by mutect2, varscan2
- OR5M10 | c.924del p.K308Nfs*17 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | catalogued as rs935599693; called by mutect2, pindel, varscan2
- OR8B2 | c.1dup p.M1? | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | catalogued as rs758985992; called by mutect2, pindel
- OTUD6A | c.92del p.N31Tfs*52 | Frame Shift Del (DEL) | VAF 88/175 reads (50%) | catalogued as COSV57972665; called by mutect2, varscan2
- P2RY6 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 153/636 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1408227663; called by muse, mutect2, varscan2
- PAPPA2 | c.5055dup p.S1686Qfs*2 | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | catalogued as rs747970462; called by mutect2, varscan2
- PARP16 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs781485616; called by muse, mutect2, varscan2
- PCLO | c.13016C>T p.P4339L | Missense Mutation (SNP) | VAF 100/493 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs760367639, COSV61640597; called by muse, mutect2, varscan2
- PDE4D | c.1354G>A p.E452K (on ENST00000340635 / NM_001104631.2; = p.E316K on NM_006203.4) | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs913974941; called by muse, mutect2, varscan2
- PFKP | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143809031; called by muse, mutect2, varscan2
- PGAM1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 98/469 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs201159774; called by muse, mutect2, varscan2
- PGLYRP3 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 130/657 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs762191895; called by muse, mutect2, varscan2
- PHETA2 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 66/270 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs772638586; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | catalogued as rs769717544; called by mutect2, varscan2
- PHOX2B | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 31/104 reads (30%) | catalogued as CM041819, COSV56930579; called by muse, mutect2, varscan2
- PIK3R2 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as rs80233027; called by muse, mutect2, varscan2
- PITRM1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0.048); catalogued as rs144796240; called by muse, mutect2, varscan2
- PKD1 | c.12070C>T p.P4024S (on ENST00000262304 / NM_001009944.3; = p.P4023S on NM_000296.4) | Missense Mutation (SNP) | VAF 211/1050 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.636); catalogued as rs771494407, COSV104375706; called by muse, mutect2, varscan2
- PKHD1L1 | c.6013A>G p.N2005D | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65742887; called by muse, varscan2
- PKN1 | c.2530G>A p.G844S | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as rs755606989; called by muse, mutect2, varscan2
- PLAG1 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 117/529 reads (22%) | catalogued as COSV100387966; called by muse, mutect2, varscan2
- PLCB3 | c.2369C>T p.T790M | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1424867148; called by muse, mutect2, varscan2
- PLCD1 | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 255/1131 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs752980022, COSV52184072; called by muse, mutect2, varscan2
- PLCH1 | c.1514G>A p.R505Q (on ENST00000340059 / NM_001130960.2; = p.R517Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1174505951; called by muse, mutect2, varscan2
- PLD5 | c.265G>A p.V89M (on ENST00000442594; = p.V27M on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762592776, COSV100138626, COSV100143621; called by muse, mutect2, varscan2
- PLEKHG4B | c.2237A>G p.D746G (on ENST00000283426; = p.D1102G on NM_052909.5) | Missense Mutation (SNP) | VAF 89/391 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757021377; called by muse, mutect2, varscan2
- PLOD3 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 112/446 reads (25%) | catalogued as rs1224664350, COSV99778157; called by muse, mutect2, varscan2
- PNPLA2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 93/368 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.472); catalogued as rs1036232298, COSV60745400; called by muse, mutect2, varscan2
- PNPLA4 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs146508989, COSV66853934; called by muse, mutect2, varscan2
- POLD1 | c.2606C>T p.S869L | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1422842883, COSV54531771; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POU2F1 | c.1132C>T p.R378C (on ENST00000541643 / NM_001365848.1; = p.R401C on NM_002697.4) | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54818783; called by muse, mutect2, varscan2
- PPFIA3 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61953040; called by muse, mutect2, varscan2
- PPP1R3A | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 92/525 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1179318748, COSV52878523; called by muse, mutect2, varscan2
- PRKACB | c.145del p.T49Pfs*13 | Frame Shift Del (DEL) | VAF 24/101 reads (24%) | catalogued as rs1291568884; called by mutect2, pindel, varscan2
- PRKD3 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 61/359 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs757179385; called by muse, mutect2, varscan2
- PROB1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs1422905873; called by muse, mutect2, varscan2
- PRR23C | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 48/237 reads (20%) | catalogued as rs768854745; called by muse, mutect2, varscan2
- PTPN21 | c.2545del p.I849Lfs*9 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as rs778292578; called by mutect2, varscan2
- PTPN3 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs193920798, COSV52701715; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRF | c.3280C>T p.R1094C | Missense Mutation (SNP) | VAF 127/468 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374873502; called by muse, mutect2, varscan2
- PUF60 | c.1028C>T p.A343V (on ENST00000526683 / NM_001362896.2; = p.A326V on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV57591834; called by muse, mutect2, varscan2
- PXDN | c.2810G>A p.R937Q | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs1440817288; called by muse, mutect2, varscan2
- PZP | c.1369C>A p.L457M | Missense Mutation (SNP) | VAF 69/362 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99739586; called by muse, mutect2, varscan2
- RAB5A | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749601586; called by muse, mutect2, varscan2
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 24/124 reads (19%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RAC3 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.35); catalogued as rs781698003; called by muse, mutect2, varscan2
- RAPGEF6 | c.4354C>T p.Q1452* | Nonsense Mutation (SNP) | VAF 26/163 reads (16%) | catalogued as rs764526893, COSV57247050; called by muse, mutect2, varscan2
- RASSF9 | c.328A>G p.M110V | Missense Mutation (SNP) | VAF 86/358 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1283742507; called by muse, mutect2, varscan2
- RAVER1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs376930823; called by muse, mutect2, varscan2
- RBL2 | c.510dup p.Q171Sfs*5 | Frame Shift Ins (INS) | VAF 26/149 reads (17%) | catalogued as rs1290780149; called by mutect2, pindel, varscan2
- RBL2 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs1372130543; called by muse, mutect2, varscan2
- RBM15B | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363020573, COSV60042749; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs762006287; called by mutect2, varscan2
- RCN3 | c.444C>T p.P148= | Splice Region (SNP) | VAF 12/56 reads (21%) | catalogued as rs1187054848; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs751982308; called by mutect2, varscan2
- RGS7 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs1181998043, COSV58537763; called by muse, mutect2, varscan2
- RGS9BP | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as rs1005826880; called by muse, mutect2, varscan2
- RHBDF2 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as rs753693526, COSV100489381; called by muse, mutect2, varscan2
- RHOT2 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs141301971; called by muse, mutect2, varscan2
- RICTOR | c.2912T>C p.V971A | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV57130216; called by muse, mutect2, varscan2
- RIPK4 | c.1786G>A p.G596R (on ENST00000352483; = p.G548R on NM_020639.3) | Missense Mutation (SNP) | VAF 164/644 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750890967; called by muse, mutect2, varscan2
- RNF152 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 97/457 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV57183866; called by muse, mutect2, varscan2
- RNF213 | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 68/447 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV60627216; called by muse, mutect2, varscan2
- RNF216 | c.556del p.R186Vfs*3 (on ENST00000425013 / NM_207116.3; = p.R243Vfs*3 on NM_207111.4) | Frame Shift Del (DEL) | VAF 45/192 reads (23%) | catalogued as COSV66289211; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 30/143 reads (21%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RRAD | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55335399, COSV55335687; called by muse, mutect2, varscan2
- RSPO1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 108/517 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0.006); catalogued as rs761409987, COSV62974352, COSV62974548; called by muse, mutect2, varscan2
- RTN2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 112/520 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1158609094, COSV55593774; called by muse, varscan2
- RUBCNL | c.958T>C p.C320R | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs983062241; called by muse, mutect2, varscan2
- SALL3 | c.3244G>A p.A1082T | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs769002198, COSV73306185; called by muse, mutect2, varscan2
- SATB2 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs1409295633; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 31/128 reads (24%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 19/107 reads (18%) | catalogued as rs763181092; called by mutect2, pindel, varscan2
- SGK3 | c.189dup p.Q64Tfs*17 | Frame Shift Ins (INS) | VAF 21/80 reads (26%) | catalogued as rs1563636611; called by mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 30/133 reads (23%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SHC3 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV101012058; called by muse, mutect2, varscan2
- SHISAL2A | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.289); catalogued as rs1424218865; called by muse, mutect2, varscan2
- SINHCAF | c.218del p.N73Tfs*6 | Frame Shift Del (DEL) | VAF 22/99 reads (22%) | catalogued as rs771414532; called by mutect2, varscan2
- SIPA1L1 | c.172del p.R58Efs*8 | Frame Shift Del (DEL) | VAF 10/105 reads (10%) | catalogued as rs1567251966; called by mutect2, pindel
- SIRT6 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1419568428; called by muse, mutect2
- SLC12A7 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs763475018; called by muse, mutect2, varscan2
- SLC13A5 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs199620361; ClinVar: uncertain significance; called by muse, varscan2
- SLC15A3 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs777200135, COSV50010570; called by muse, mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 99/370 reads (27%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC18A2 | c.1172T>C p.V391A | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as rs1206622494; called by muse, mutect2, varscan2
- SLC20A2 | c.1882G>A p.V628M | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs200761348; called by muse, mutect2, varscan2
- SLC22A11 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57253201; called by muse, mutect2, varscan2
- SLC2A10 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 161/656 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs774497964, COSV63716048, COSV63716497; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC38A10 | c.3154C>T p.R1052* | Nonsense Mutation (SNP) | VAF 52/212 reads (25%) | catalogued as rs375255904; called by muse, mutect2, varscan2
- SLC4A10 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759420527, COSV55768636; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | catalogued as rs759883814, COSV56092392; called by mutect2, pindel, varscan2
- SLC5A2 | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 151/757 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as rs761264242, COSV57894283; called by muse, mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 86/384 reads (22%) | catalogued as rs747405143; called by mutect2, varscan2
- SORBS2 | c.2506C>T p.R836C (on ENST00000284776 / NM_021069.5; = p.R402C on NM_003603.6) | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as rs756993379; called by muse, mutect2, varscan2
- SORCS1 | c.2709G>T p.K903N | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); catalogued as COSV53909084; called by muse, mutect2, varscan2
- SPAG6 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs753729413, COSV57618895; called by muse, mutect2, varscan2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | catalogued as rs750890082; called by mutect2, varscan2
- SPOPL | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs757299951, COSV104381324; called by muse, mutect2, varscan2
- SPPL3 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.357); catalogued as COSV62234603; called by muse, mutect2, varscan2
- SPPL3 | c.102-1G>T p.X34_splice | Splice Site (SNP) | VAF 20/50 reads (40%) | catalogued as COSV62231254; called by muse, mutect2, varscan2
- SPRED3 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs1351302155; called by muse, mutect2, varscan2
- SPTB | c.5383G>A p.A1795T | Missense Mutation (SNP) | VAF 98/401 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.812); catalogued as rs749332448; called by muse, mutect2, varscan2
- SRCIN1 | c.787G>A p.A263T (on ENST00000621492; = p.A229T on NM_025248.3) | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs1454117602; called by muse, mutect2, varscan2
- SREK1IP1 | c.51dup p.C18Mfs*10 | Frame Shift Ins (INS) | VAF 19/180 reads (11%) | catalogued as rs747293993; called by mutect2, pindel, varscan2
- SSC5D | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs984410169; called by muse, mutect2, varscan2
- SSH1 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 82/353 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754103782, COSV58457409, COSV58458416; called by muse, mutect2, varscan2
- STH | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 87/362 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); catalogued as rs1430554528; called by muse, mutect2, varscan2
- SVEP1 | c.4686G>T p.E1562D | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.182); catalogued as COSV65682567; called by muse, mutect2, varscan2
- TAP2 | c.1272+6C>T | Splice Region (SNP) | VAF 88/439 reads (20%) | catalogued as rs773119824; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 40/132 reads (30%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D4 | c.3103A>G p.M1035V | Missense Mutation (SNP) | VAF 145/671 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1406624406; called by muse, mutect2, varscan2
- TBL3 | c.1535A>G p.Q512R | Missense Mutation (SNP) | VAF 111/480 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs773306472; called by muse, mutect2, varscan2
- TBL3 | c.1993C>T p.R665W | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs770970273; called by muse, mutect2, varscan2
- TBX3 | c.911G>A p.R304Q (on ENST00000257566 / NM_016569.4; = p.R284Q on NM_005996.4) | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV57469903; called by muse, mutect2, varscan2
- TCF20 | c.4043G>A p.R1348Q | Missense Mutation (SNP) | VAF 99/456 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1432923771; called by muse, mutect2, varscan2
- TCF3 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as rs753137385; called by muse, mutect2, varscan2
- TCF3 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs143406385; called by muse, mutect2, varscan2
- TCHP | c.522del p.K174Nfs*26 | Frame Shift Del (DEL) | VAF 52/206 reads (25%) | catalogued as rs763438715; called by mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 50/160 reads (31%) | catalogued as rs763321097; called by mutect2, varscan2
- TELO2 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 98/358 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1219804292; called by muse, mutect2
- TEX12 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54784444; called by muse, mutect2, varscan2
- THBS2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as rs769039736, COSV64680136; called by muse, mutect2, varscan2
- TJP1 | c.5206G>A p.V1736I | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.606); catalogued as rs369915729; called by muse, mutect2, varscan2
- TLR9 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1479085302; called by muse, mutect2, varscan2
- TLX3 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs1378477591; called by muse, mutect2, varscan2
- TMC8 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 114/608 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as rs138026813, COSV59208888; called by muse, mutect2, varscan2
- TMEM100 | c.296dup p.L99Ffs*91 | Frame Shift Ins (INS) | VAF 32/185 reads (17%) | catalogued as rs894486999; called by mutect2, varscan2
- TMEM132E | c.573dup p.R192Qfs*115 (on ENST00000321639; = p.R282Qfs*115 on NM_001304438.2) | Frame Shift Ins (INS) | VAF 28/238 reads (12%) | catalogued as rs766733228; called by mutect2, pindel, varscan2
- TNP1 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 180/680 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.89); catalogued as rs367585957; called by muse, mutect2, varscan2
- TNRC18 | c.4627dup p.R1543Pfs*10 | Frame Shift Ins (INS) | VAF 17/107 reads (16%) | catalogued as rs754233336; called by mutect2, varscan2
- TNXB | c.12214G>A p.V4072M (on ENST00000647633; = p.V3825M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/926 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs550641852, COSV64481562; called by muse, mutect2
- TNXB | c.2623G>A p.V875I | Missense Mutation (SNP) | VAF 138/676 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs377480086; called by muse, mutect2, varscan2
- TOMM40L | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs1252476104, COSV100915612; called by muse, mutect2, varscan2
- TP53 | c.880del p.E294Sfs*51 | Frame Shift Del (DEL) | VAF 122/501 reads (24%) | catalogued as CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; called by mutect2, pindel, varscan2
- TPTE | c.712G>C p.D238H (on ENST00000618007 / NM_199261.4; = p.D220H on NM_199259.4) | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763108699; called by muse, mutect2
- TRAP1 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs139636268; called by muse, mutect2, varscan2
- TRDN | c.1905del p.V636Sfs*13 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as COSV100523798; called by mutect2, pindel, varscan2
- TRIM17 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs147811733; called by muse, mutect2, varscan2
- TRIM50 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as rs147515596; called by muse, mutect2, varscan2
- TRPC3 | c.890C>T p.P297L (on ENST00000379645 / NM_001366479.2; = p.P224L on NM_003305.2) | Missense Mutation (SNP) | VAF 114/573 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53374285; called by muse, mutect2, varscan2
- TRPM4 | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.663); catalogued as rs564964090; called by muse, mutect2, varscan2
- TRPM4 | c.3584G>A p.R1195H | Missense Mutation (SNP) | VAF 129/543 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1295618759; called by muse, mutect2, varscan2
- TRPS1 | c.850C>T p.R284C (on ENST00000220888 / NM_001330599.2; = p.R297C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs760453058, COSV55257698; called by muse, mutect2, varscan2
- TSHR | c.1270G>A p.V424I | Missense Mutation (SNP) | VAF 185/845 reads (22%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.997); catalogued as rs587778742; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- TSSK1B | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 109/480 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs756692400, COSV66816347; called by muse, mutect2, varscan2
- TTC21B | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs752711108, COSV54629966; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs756650873; called by mutect2, varscan2
- TTN | c.33725del p.P11242Qfs*45 (on ENST00000591111; = p.P10315Qfs*45 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/118 reads (19%) | catalogued as COSV59920295, COSV59947848; called by mutect2, pindel, varscan2
- TTN | c.9448C>T p.R3150* (on ENST00000591111; = p.R3104* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 116/499 reads (23%) | catalogued as rs146572907; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA8 | c.739del p.A247Pfs*45 | Frame Shift Del (DEL) | VAF 104/447 reads (23%) | catalogued as COSV100283180; called by mutect2, pindel, varscan2
- TULP4 | c.3064dup p.V1022Gfs*80 | Frame Shift Ins (INS) | VAF 20/111 reads (18%) | catalogued as rs752011727; called by mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 42/185 reads (23%) | catalogued as rs763652408; called by mutect2, varscan2
- UGGT1 | c.3382C>T p.R1128W | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs773911386; called by muse, mutect2, varscan2
- UHRF1 | c.1394del p.G465Afs*98 (on ENST00000612630 / NM_001290050.1; = p.G478Afs*98 on NM_013282.4) | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as COSV53573526, COSV53573895; called by mutect2, pindel, varscan2
- UNC13C | c.3238G>A p.V1080I | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs561425967, COSV52840573, COSV52849325; called by muse, mutect2, varscan2
- UNC93A | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772759538; called by muse, mutect2, varscan2
- UPK3B | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as rs147864867; called by muse, mutect2
- USH2A | c.7061G>A p.R2354H | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs201386640, CM065510, COSV56331304; ClinVar: uncertain significance; called by muse, mutect2
- VWA8 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs758531436; called by muse, mutect2, varscan2
- VWDE | c.4742G>A p.C1581Y | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs371756568; called by muse, mutect2, varscan2
- WDR87 | c.6187del p.R2063Gfs*11 | Frame Shift Del (DEL) | VAF 50/238 reads (21%) | catalogued as rs1281550425; called by mutect2, pindel, varscan2
- WFS1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 133/551 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1024420191, CM1410167, COSV56987592; called by muse, mutect2, varscan2
- WFS1 | c.1949A>G p.Y650C | Missense Mutation (SNP) | VAF 152/650 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765322804, CD041184; called by muse, mutect2, varscan2
- WRAP73 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.357); catalogued as rs376319228; called by muse, mutect2, varscan2
- WT1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV60076154; called by muse, mutect2, varscan2
- YARS1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 154/659 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754708654; called by mutect2, varscan2
- YJU2 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs1443688008, COSV99508192; called by muse, mutect2, varscan2
- ZBTB4 | c.2878del p.A960Pfs*13 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | catalogued as rs1422959685; called by mutect2, pindel, varscan2
- ZDHHC8 | c.1253del p.P418Hfs*16 | Frame Shift Del (DEL) | VAF 57/279 reads (20%) | catalogued as COSV57710916; called by mutect2, pindel, varscan2
- ZFAND1 | c.19G>T p.G7W | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569073548; called by muse, mutect2, varscan2
- ZFYVE1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.097); catalogued as rs552662436; called by muse, mutect2, varscan2
- ZMYM5 | c.2006C>T p.T669M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs370969778; called by muse, mutect2, varscan2
- ZNF219 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391804643; called by muse, mutect2, varscan2
- ZNF358 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV51177332; called by muse, mutect2, varscan2
- ZNF444 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV61363670; called by muse, varscan2
- ZNF471 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.56); catalogued as rs960505204; called by muse, mutect2
- ZNF500 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs750550845; called by muse, mutect2, varscan2
- ZNF512B | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as rs749184392, COSV53877541; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 35/141 reads (25%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF536 | c.2407C>T p.R803W | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140147461; called by muse, mutect2, varscan2
- ZNF540 | c.843dup p.S282* | Frame Shift Ins (INS) | VAF 34/181 reads (19%) | catalogued as rs757107073; called by mutect2, varscan2
- ZNF609 | c.4227del p.R1410Gfs*30 | Frame Shift Del (DEL) | VAF 20/135 reads (15%) | catalogued as COSV58580120; called by mutect2, pindel, varscan2
- ABCA13 | c.4763A>G p.K1588R | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2
- ABCA2 | c.1608G>T p.Q536H (on ENST00000614293; = p.Q506H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ABCB1 | c.2860G>A p.A954T | Missense Mutation (SNP) | VAF 94/366 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ABCB4 | c.1141del p.S381Qfs*32 | Frame Shift Del (DEL) | VAF 56/332 reads (17%) | called by mutect2, pindel, varscan2
- ABCC8 | c.1037T>A p.V346D | Missense Mutation (SNP) | VAF 114/457 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ABLIM3 | c.1546C>T p.H516Y | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- AC010973.3 | c.44del p.K15Rfs*? | Frame Shift Del (DEL) | VAF 48/230 reads (21%) | called by mutect2, pindel, varscan2
- ACOT11 | c.1615del p.D539Tfs*3 | Frame Shift Del (DEL) | VAF 25/132 reads (19%) | called by mutect2, varscan2
- ACSF2 | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACTRT2 | c.163_173delinsTACTTTGTG p.K55Yfs*30 | Frame Shift Del (DEL) | VAF 28/162 reads (17%) | called by mutect2*, pindel, varscan2*
- ADCY1 | c.2141del p.G714Afs*28 | Frame Shift Del (DEL) | VAF 37/151 reads (25%) | called by mutect2, pindel, varscan2
- ADGRA2 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- ADGRL3 | c.2780T>C p.V927A (on ENST00000506720 / NM_001322402.2; = p.V859A on NM_015236.6) | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- AGPS | c.1901T>C p.V634A | Missense Mutation (SNP) | VAF 89/415 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- AHNAK | c.373A>G p.K125E | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP1 | c.1410dup p.S471Qfs*2 | Frame Shift Ins (INS) | VAF 77/390 reads (20%) | called by pindel, varscan2
- ALK | c.4688C>T p.T1563I | Missense Mutation (SNP) | VAF 163/733 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- ANKRD33B | c.170C>A p.S57Y | Missense Mutation (SNP) | VAF 15/308 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANKRD62 | c.582del p.K194Nfs*4 | Frame Shift Del (DEL) | VAF 18/130 reads (14%) | called by mutect2, pindel, varscan2
- AP5B1 | c.260del p.P87Rfs*71 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- APLP1 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- APOB | c.2968G>T p.A990S | Missense Mutation (SNP) | VAF 104/424 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.187); called by mutect2, varscan2
- APPL2 | c.416-3del | Splice Region (DEL) | VAF 52/239 reads (22%) | called by mutect2, pindel, varscan2
- AQR | c.3473C>T p.P1158L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- AQR | c.369del p.F123Lfs*5 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by pindel, varscan2
- ARHGAP27 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ARHGEF7 | c.1397T>C p.I466T (on ENST00000375741 / NM_001113511.2; = p.I288T on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/421 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2
- ARID5B | c.581T>C p.I194T | Missense Mutation (SNP) | VAF 135/655 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ART3 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 42/210 reads (20%) | called by muse, mutect2, varscan2
- ASB14 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ASGR2 | c.511+2T>C p.X171_splice | Splice Site (SNP) | VAF 68/256 reads (27%) | called by muse, mutect2, varscan2
- ASZ1 | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATG2B | c.5050G>T p.A1684S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATP6V0C | c.272_274del p.L91del | In Frame Del (DEL) | VAF 33/86 reads (38%) | called by pindel, varscan2
- ATP7A | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ATRX | c.3962A>T p.N1321I | Missense Mutation (SNP) | VAF 84/155 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATXN1 | c.1953del p.F651Lfs*40 | Frame Shift Del (DEL) | VAF 36/127 reads (28%) | called by mutect2, pindel, varscan2
- AVPR1A | c.872A>C p.K291T | Missense Mutation (SNP) | VAF 108/452 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AZIN1 | c.123del p.F41Lfs*9 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | called by mutect2, varscan2
- B2M | c.276del p.T93Lfs*10 | Frame Shift Del (DEL) | VAF 140/400 reads (35%) | called by mutect2, varscan2
- B4GALT3 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 80/358 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.062); called by mutect2, varscan2
- BAG2 | c.307A>G p.N103D | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- BICC1 | c.1696del p.I566Sfs*5 | Frame Shift Del (DEL) | VAF 25/125 reads (20%) | called by mutect2, pindel, varscan2
- BNIP1 | c.453G>C p.Q151H | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- BTN1A1 | c.805T>C p.W269R | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- C10orf71 | c.3632C>T p.P1211L | Missense Mutation (SNP) | VAF 70/344 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- C11orf42 | c.870A>G p.S290= | Splice Region (SNP) | VAF 32/166 reads (19%) | called by muse, mutect2, varscan2
- C11orf98 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- C16orf86 | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 72/297 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- C20orf194 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CACNA1E | c.5569A>G p.M1857V | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CARMIL1 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- CASKIN1 | c.2153G>A p.S718N | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- CASKIN2 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 82/339 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CASP12 | c.81del p.F27Lfs*4 | Frame Shift Del (DEL) | VAF 44/213 reads (21%) | called by mutect2, pindel, varscan2
- CCDC105 | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC127 | c.545A>T p.K182M | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2
- CCDC136 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 64/233 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CCDC178 | c.1519A>G p.T507A | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC62 | c.700A>C p.N234H | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- CDKN2AIPNL | c.141C>A p.H47Q | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- CEP250 | c.1795G>A p.V599I | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CEP290 | c.4927A>T p.K1643* | Nonsense Mutation (SNP) | VAF 14/155 reads (9%) | called by muse, mutect2
- CETN3 | c.189del p.A64Lfs*4 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- CFAP74 | c.1658G>A p.G553D | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- CFHR5 | c.344A>T p.N115I | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- CHP1 | c.535-2A>G p.X179_splice | Splice Site (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- CHRDL2 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- CIP2A | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CLIP2 | c.2326G>A p.G776S | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL14A1 | c.2803T>G p.L935V | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL23A1 | c.1575T>A p.C525* | Nonsense Mutation (SNP) | VAF 31/146 reads (21%) | called by muse, varscan2
- COL23A1 | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 64/277 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); called by mutect2, varscan2
- COL7A1 | c.5979G>T p.E1993D | Missense Mutation (SNP) | VAF 140/691 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.358); called by mutect2, varscan2
- COLQ | c.572A>G p.K191R | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COQ8A | c.1256+11del | Splice Region (DEL) | VAF 132/683 reads (19%) | called by pindel, varscan2
- COTL1 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- CPVL | c.1251del p.V418Ffs*24 | Frame Shift Del (DEL) | VAF 23/142 reads (16%) | called by mutect2, varscan2
- CRK | c.404A>C p.E135A | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2
- CRMP1 | c.1685del p.P562Lfs*21 | Frame Shift Del (DEL) | VAF 23/141 reads (16%) | called by mutect2, pindel, varscan2
- CRTC2 | c.1378T>A p.S460T | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CSTF3 | c.1317del p.K439Nfs*33 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- CUL9 | c.6427_6429del p.E2143del | In Frame Del (DEL) | VAF 35/163 reads (21%) | called by mutect2, pindel, varscan2
- DBNL | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2
- DCLK1 | c.1412del p.G471Efs*25 | Frame Shift Del (DEL) | VAF 20/114 reads (18%) | called by mutect2, pindel, varscan2
- DENND11 | c.587del p.K196Rfs*31 | Frame Shift Del (DEL) | VAF 30/196 reads (15%) | called by mutect2, pindel, varscan2
- DES | c.1108C>A p.L370M | Missense Mutation (SNP) | VAF 92/399 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DHDH | c.896-1G>T p.X299_splice | Splice Site (SNP) | VAF 37/139 reads (27%) | called by muse, mutect2, varscan2
- DIAPH2 | c.1811C>A p.P604H | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- DIDO1 | c.2613dup p.Q872Tfs*8 | Frame Shift Ins (INS) | VAF 59/260 reads (23%) | called by mutect2, pindel, varscan2
- DNAH2 | c.10077C>A p.C3359* | Nonsense Mutation (SNP) | VAF 56/206 reads (27%) | called by mutect2, varscan2
- DNAH3 | c.6581del p.G2194Efs*14 | Frame Shift Del (DEL) | VAF 38/180 reads (21%) | called by mutect2, pindel, varscan2
- DNAH9 | c.5392-2A>G p.X1798_splice | Splice Site (SNP) | VAF 62/204 reads (30%) | called by muse, mutect2, varscan2
- DNPH1 | c.268G>C p.V90L | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.246); called by muse, mutect2
- DOCK10 | c.3952T>C p.S1318P | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DOCK8 | c.5223G>T p.T1741= | Splice Region (SNP) | VAF 98/438 reads (22%) | called by mutect2, varscan2
- DOK3 | c.1256A>T p.K419M | Missense Mutation (SNP) | VAF 113/434 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- DTL | c.12T>A p.N4K | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DYNC1I1 | c.511C>A p.Q171K | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- E2F3 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- E4F1 | c.2148del p.E717Rfs*3 | Frame Shift Del (DEL) | VAF 108/471 reads (23%) | called by mutect2, pindel, varscan2
- EEA1 | c.1016T>G p.L339R | Missense Mutation (SNP) | VAF 59/292 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- EIF3M | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- EIF4G1 | c.1108C>A p.L370M (on ENST00000346169 / NM_198241.3; = p.L174M on NM_004953.5) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ELOA | c.1394dup p.N465Kfs*2 | Frame Shift Ins (INS) | VAF 18/92 reads (20%) | called by mutect2, varscan2
- EOLA2 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- EPB41L3 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 104/414 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- EPG5 | c.1909A>T p.R637W | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPHA7 | c.2117C>A p.P706Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ESPL1 | c.1058G>T p.R353M | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by mutect2, varscan2
- ESYT3 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ETV6 | c.1264A>C p.T422P | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM111B | c.1910A>G p.H637R | Missense Mutation (SNP) | VAF 64/299 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FAM122A | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FAM126B | c.106del p.T36Hfs*47 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- FAM163A | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM169A | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FAM178B | c.932T>G p.L311R | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- FAM71E2 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FASN | c.6398A>G p.H2133R | Missense Mutation (SNP) | VAF 30/713 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.711); called by muse, mutect2
- FAT1 | c.2876C>T p.S959F | Missense Mutation (SNP) | VAF 138/516 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- FAT2 | c.3889A>G p.T1297A | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- FAT3 | c.2777dup p.L926Ffs*3 | Frame Shift Ins (INS) | VAF 80/357 reads (22%) | called by mutect2, varscan2
- FAT3 | c.3588dup p.A1197Cfs*51 | Frame Shift Ins (INS) | VAF 69/274 reads (25%) | called by mutect2, varscan2
- FCGR2A | c.731del p.K244Sfs*11 (on ENST00000271450 / NM_001136219.3; = p.K243Sfs*11 on NM_021642.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 36/203 reads (18%) | called by mutect2, pindel, varscan2
- FIGLA | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FLNC | c.1913A>G p.Y638C | Missense Mutation (SNP) | VAF 24/616 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FLNC | c.8069G>A p.R2690Q | Missense Mutation (SNP) | VAF 96/439 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.063); called by muse, varscan2
- FNIP2 | c.2255G>A p.S752N | Missense Mutation (SNP) | VAF 16/510 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- FOCAD | c.3535C>A p.Q1179K | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FOXD3 | c.1424G>T p.W475L | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FOXI3 | c.929C>A p.P310H | Missense Mutation (SNP) | VAF 131/614 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- FRMD4A | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2
- FUT9 | c.356A>T p.N119I | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FYB1 | c.416T>G p.L139R | Missense Mutation (SNP) | VAF 71/449 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- FZD7 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 18/269 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2
- GBP1 | c.1202A>G p.E401G | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- GDF1 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GIMAP2 | c.380A>C p.Q127P | Missense Mutation (SNP) | VAF 124/639 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- GLOD4 | c.667del p.Q223Rfs*7 (on ENST00000301328 / NM_001366247.1; = p.Q208Rfs*7 on NM_016080.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 30/133 reads (23%) | called by mutect2, pindel, varscan2
- GLYCTK | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 102/410 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GMIP | c.790-2A>G p.X264_splice | Splice Site (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- GOLGA3 | c.2314C>T p.Q772* | Nonsense Mutation (SNP) | VAF 86/358 reads (24%) | called by muse, mutect2, varscan2
- GPLD1 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.102); called by muse, varscan2
- GPR142 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 98/420 reads (23%) | called by muse, mutect2, varscan2
- GPR157 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- GRAMD1A | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- GRIA2 | c.352dup p.T118Nfs*21 | Frame Shift Ins (INS) | VAF 77/438 reads (18%) | called by mutect2, pindel, varscan2
- GRIA4 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- GRIN2A | c.928T>C p.F310L | Missense Mutation (SNP) | VAF 106/437 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GRM4 | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 128/448 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAND2 | c.282del p.P95Rfs*4 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel
- HELZ2 | c.2525T>C p.L842P (on ENST00000467148 / NM_001037335.2; = p.L273P on NM_033405.3) | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HIPK3 | c.284_285del p.I95Sfs*37 | Frame Shift Del (DEL) | VAF 83/434 reads (19%) | called by mutect2, pindel, varscan2
- HMCN1 | c.13586A>G p.H4529R | Missense Mutation (SNP) | VAF 115/495 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HS3ST2 | c.500G>T p.R167M | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by mutect2, varscan2
- HUWE1 | c.12404A>G p.H4135R | Missense Mutation (SNP) | VAF 160/363 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- IARS2 | c.2754G>A p.M918I | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IFT140 | c.800_802del p.E267del | In Frame Del (DEL) | VAF 19/114 reads (17%) | called by pindel, varscan2
- IGSF6 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 145/560 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- IL17REL | c.21G>T p.E7D | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- INHBA | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- INVS | c.1258G>C p.D420H | Missense Mutation (SNP) | VAF 86/342 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IPO13 | c.436A>G p.M146V | Missense Mutation (SNP) | VAF 74/393 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IRF8 | c.171dup p.K58* | Frame Shift Ins (INS) | VAF 92/511 reads (18%) | called by mutect2, pindel, varscan2
- ITIH2 | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ITPR3 | c.7224A>G p.T2408= | Splice Region (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
- ITSN2 | c.953T>A p.L318* | Nonsense Mutation (SNP) | VAF 21/141 reads (15%) | called by muse, mutect2, varscan2
- JRKL | c.279del p.N95Ifs*32 | Frame Shift Del (DEL) | VAF 45/199 reads (23%) | called by mutect2, pindel, varscan2
- KCNB1 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 73/310 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNIP3 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNJ3 | c.1037A>G p.H346R | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- KHSRP | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- KIAA1217 | c.2251del p.V751Wfs*15 | Frame Shift Del (DEL) | VAF 35/174 reads (20%) | called by mutect2, pindel, varscan2
- KIF20B | c.2548T>C p.S850P (on ENST00000371728 / NM_001284259.2; = p.S810P on NM_016195.4) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- KIF5B | c.1052dup p.N351Kfs*2 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | called by mutect2, varscan2
- KIR3DL2 | c.437C>G p.S146* | Nonsense Mutation (SNP) | VAF 83/398 reads (21%) | called by muse, mutect2, varscan2
- KRT6A | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 92/741 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- LACTB2 | c.309del p.K103Nfs*12 | Frame Shift Del (DEL) | VAF 20/137 reads (15%) | called by mutect2, pindel, varscan2
- LAMA5 | c.1763G>A p.G588D | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- LARGE1 | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 24/688 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0.088); called by muse, mutect2
- LILRB3 | c.956-1G>T p.X319_splice | Splice Site (SNP) | VAF 9/152 reads (6%) | called by muse, mutect2
- LINGO1 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- LKAAEAR1 | c.542C>T p.T181I (on ENST00000302096 / NM_001353425.1; = p.D210= on NM_001007125.1) | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- LLPH | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- LTBP4 | c.1019del p.P340Qfs*62 (on ENST00000308370 / NM_001042544.1; = p.P303Qfs*62 on NM_003573.2) | Frame Shift Del (DEL) | VAF 41/215 reads (19%) | called by mutect2, pindel, varscan2
- LYRM7 | c.47G>T p.R16M | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEC3 | c.1540A>C p.T514P | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MAGI3 | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP1B | c.3574del p.T1192Qfs*40 | Frame Shift Del (DEL) | VAF 104/415 reads (25%) | called by mutect2, pindel, varscan2
- MAP2 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- MAP3K20 | c.1730T>C p.L577P | Missense Mutation (SNP) | VAF 14/315 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- MDN1 | c.4517T>C p.I1506T | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.071); called by muse, varscan2
- MED13 | c.6401T>C p.L2134S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED4 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- METTL11B | c.*4del | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | called by mutect2, pindel, varscan2
- MFAP3L | c.686A>G p.E229G | Missense Mutation (SNP) | VAF 98/423 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MLNR | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- MROH2A | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- MRPL42 | c.93T>G p.C31W | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- MTG1 | c.986del p.P329Rfs*28 | Frame Shift Del (DEL) | VAF 42/166 reads (25%) | called by mutect2, varscan2
- MTIF2 | c.1767del p.G590Efs*2 | Frame Shift Del (DEL) | VAF 40/170 reads (24%) | called by mutect2, pindel, varscan2
- MUC2 | c.1781_1784del p.T594Rfs*77 | Frame Shift Del (DEL) | VAF 24/133 reads (18%) | called by mutect2, pindel, varscan2
- MYEOV | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 110/527 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- MYH14 | c.5983del p.Q1995Sfs*33 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | called by mutect2, pindel, varscan2
- MYH7B | c.4832T>C p.L1611P | Missense Mutation (SNP) | VAF 73/269 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MYNN | c.1817del p.L606Yfs*19 | Frame Shift Del (DEL) | VAF 55/232 reads (24%) | called by mutect2, pindel, varscan2
- MYO15A | c.10450G>A p.D3484N | Missense Mutation (SNP) | VAF 110/498 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- MYO9B | c.1274A>G p.E425G | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYOF | c.2429G>A p.C810Y | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV1 | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 85/358 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAV2 | c.6652G>A p.V2218M (on ENST00000396087 / NM_001244963.2; = p.V2159M on NM_145117.5) | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NBEAL1 | c.3815del p.L1272* | Frame Shift Del (DEL) | VAF 30/123 reads (24%) | called by mutect2, pindel, varscan2
- NCKAP5L | c.1570del p.S524Hfs*64 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | called by mutect2, pindel, varscan2
- NDUFS3 | c.689T>C p.F230S | Missense Mutation (SNP) | VAF 96/447 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NF1 | c.5537G>A p.R1846Q (on ENST00000358273 / NM_001042492.3; = p.R1825Q on NM_000267.3) | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- NIN | c.3899T>A p.V1300D | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- NME4 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 84/429 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NNT | c.2890C>A p.P964T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOMO1 | c.3640G>T p.A1214S | Missense Mutation (SNP) | VAF 64/594 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by mutect2, varscan2
- NPAS1 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- NRBF2 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- NRDC | c.616del p.T206Lfs*17 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, varscan2
- NT5DC4 | c.154T>C p.Y52H | Missense Mutation (SNP) | VAF 70/412 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NTMT1 | c.99del p.Y34Mfs*20 | Frame Shift Del (DEL) | VAF 60/254 reads (24%) | called by mutect2, pindel, varscan2
- NUCKS1 | c.430A>G p.S144G | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2
- NUDT15 | c.221dup p.N74Kfs*13 | Frame Shift Ins (INS) | VAF 26/167 reads (16%) | called by mutect2, varscan2
- NXPH1 | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 108/493 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NYNRIN | c.2831T>C p.L944P | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OLIG3 | c.160del p.E54Kfs*31 | Frame Shift Del (DEL) | VAF 73/293 reads (25%) | called by mutect2, pindel, varscan2
- OMD | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OXSM | c.537del p.F179Lfs*45 | Frame Shift Del (DEL) | VAF 125/621 reads (20%) | called by mutect2, pindel, varscan2
- P2RY1 | c.1111A>G p.T371A | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PAN2 | c.1199T>C p.V400A | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PATZ1 | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCDH11X | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 185/408 reads (45%) | called by muse, mutect2, varscan2
- PCDH7 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA12 | c.558del p.D187Ifs*8 | Frame Shift Del (DEL) | VAF 50/292 reads (17%) | called by mutect2, pindel, varscan2
- PCDHA2 | c.1958A>G p.D653G | Missense Mutation (SNP) | VAF 28/544 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA5 | c.2357A>G p.E786G | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCLO | c.5953C>T p.Q1985* | Nonsense Mutation (SNP) | VAF 36/454 reads (8%) | called by muse, mutect2
- PCLO | c.719C>A p.S240Y | Missense Mutation (SNP) | VAF 24/494 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2
- PCNX2 | c.4231G>T p.G1411C | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by mutect2, varscan2
- PCYOX1L | c.442del p.V148Wfs*9 | Frame Shift Del (DEL) | VAF 40/215 reads (19%) | called by mutect2, pindel, varscan2
- PDZD2 | c.5528dup p.V1845Rfs*6 | Frame Shift Ins (INS) | VAF 36/168 reads (21%) | called by mutect2, varscan2
- PFKP | c.1397T>C p.V466A | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- PHF14 | c.546del p.K182Nfs*19 | Frame Shift Del (DEL) | VAF 58/243 reads (24%) | called by mutect2, varscan2
- PHOSPHO1 | c.421C>A p.L141M | Missense Mutation (SNP) | VAF 116/450 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- PIEZO2 | c.4598del p.K1533Sfs*34 | Frame Shift Del (DEL) | VAF 36/118 reads (31%) | called by mutect2, varscan2
- PLA2G2C | c.170A>G p.D57G | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- PLA2G6 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 85/315 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLIN2 | c.736del p.S246Afs*14 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | called by mutect2, pindel, varscan2
- PLK3 | c.1011del p.N338Tfs*35 | Frame Shift Del (DEL) | VAF 47/212 reads (22%) | called by mutect2, varscan2
- PLXNB1 | c.6083G>A p.G2028D | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PMS1 | c.1205del p.N402Tfs*6 | Frame Shift Del (DEL) | VAF 59/268 reads (22%) | called by mutect2, pindel, varscan2
- PNPLA3 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 16/447 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.783); called by muse, mutect2
- PNPLA5 | c.268T>C p.Y90H | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- POGK | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 79/359 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- PP2D1 | c.359C>A p.S120Y | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- PPP1R13L | c.1978G>A p.G660S | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- PPP1R37 | c.740T>C p.M247T | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP2R2D | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2
- PPP2R5B | c.723-1G>T p.X241_splice | Splice Site (SNP) | VAF 64/282 reads (23%) | called by mutect2, varscan2
- PPP4R3C | c.85T>G p.S29A | Missense Mutation (SNP) | VAF 76/153 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PRDM8 | c.682del p.C228Afs*73 | Frame Shift Del (DEL) | VAF 44/226 reads (19%) | called by pindel, varscan2
- PRKDC | c.8489dup p.N2830Kfs*16 | Frame Shift Ins (INS) | VAF 20/93 reads (22%) | called by mutect2, varscan2
- PRPSAP1 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRR12 | c.722C>A p.P241H (on ENST00000615927; = p.P1062H on NM_020719.3) | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- PRSS55 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSD | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PSD2 | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PSMG2 | c.30del p.D11Tfs*8 | Frame Shift Del (DEL) | VAF 26/99 reads (26%) | called by mutect2, varscan2
- PTBP2 | c.406_407dup p.Q137Sfs*9 (on ENST00000426398 / NM_001300986.2; = p.Q129Sfs*9 on NM_021190.4) | Frame Shift Ins (INS) | VAF 12/109 reads (11%) | called by mutect2, varscan2
- PTPRCAP | c.19T>G p.L7V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- RANBP3L | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RB1CC1 | c.912del p.F304Lfs*6 | Frame Shift Del (DEL) | VAF 76/352 reads (22%) | called by mutect2, varscan2
- RCN3 | c.857T>C p.L286P | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- RHOBTB2 | c.938del p.G313Afs*82 | Frame Shift Del (DEL) | VAF 23/169 reads (14%) | called by mutect2, pindel, varscan2
- RSPH6A | c.1887G>A p.W629* | Nonsense Mutation (SNP) | VAF 24/118 reads (20%) | called by muse, mutect2, varscan2
- RUNDC3B | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- S100A7A | c.116A>G p.N39S | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- SAMD11 | c.1372C>T p.Q458* | Nonsense Mutation (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- SBNO2 | c.2846G>A p.G949D | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- SCAF1 | c.3540del p.T1181Pfs*28 | Frame Shift Del (DEL) | VAF 48/208 reads (23%) | called by mutect2, varscan2
- SCLT1 | c.167del p.L56* | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | called by mutect2, pindel, varscan2
- SCN2A | c.1497del p.E500Sfs*2 | Frame Shift Del (DEL) | VAF 59/315 reads (19%) | called by mutect2, pindel, varscan2
- SCN9A | c.910del p.Y304Ifs*28 | Frame Shift Del (DEL) | VAF 25/111 reads (23%) | called by mutect2, pindel, varscan2
- SDAD1 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SELENOH | c.139T>C p.Y47H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SEPTIN7 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINI2 | c.77del p.N26Ifs*27 | Frame Shift Del (DEL) | VAF 69/313 reads (22%) | called by mutect2, pindel, varscan2
- SETX | c.10T>C p.C4R | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SF3B6 | c.271T>C p.Y91H | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SGSM3 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 84/339 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- SHROOM3 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 166/691 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SIGLEC11 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 78/320 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.678); called by mutect2, varscan2
- SIGLEC6 | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIX3 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by mutect2, varscan2
- SLC15A1 | c.490del p.S164Pfs*48 | Frame Shift Del (DEL) | VAF 32/114 reads (28%) | called by mutect2, pindel, varscan2
- SLC18A3 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 116/475 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC26A8 | c.1338G>T p.M446I | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC2A14 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SLC5A10 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 84/313 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLCO3A1 | c.1763C>A p.P588H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA5 | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- SMCHD1 | c.2180G>A p.G727E | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SMYD4 | c.77C>T p.T26I | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SNAI3 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNTG1 | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SOGA3 | c.2835dup p.V946Cfs*28 | Frame Shift Ins (INS) | VAF 8/56 reads (14%) | called by mutect2, pindel
508 further variants in this file (86 protein-altering or splice-affecting, 243 silent, 179 other) are not listed here.
